Somatic mutation profile of tumor specimen ALCH-B0FO-TTP1-A (aliquot ALCH-B0FO-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0FO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.7 years (21,815 days).
Specimen ALCH-B0FO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64a778e5-4c57-42a4-a655-d609f777372a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0FO-NB1-A (Blood Derived Normal), aliquot ALCH-B0FO-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13c938a0-9199-4039-82b7-f5cc1f326e9e

The open-access MAF lists 305 somatic variants for this specimen: 202 protein-altering or splice-affecting, 66 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 66, Intron 22, Nonsense Mutation 13, RNA 7, Splice Site 7, Frame Shift Del 4, 3'UTR 3, 5'Flank 3, Splice Region 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLI3 | c.1028+1G>A p.X343_splice | Splice Site (SNP) | VAF 57/327 reads (17%) | catalogued as rs1375768446; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-2A>T p.X187_splice | Splice Site (SNP) | VAF 75/365 reads (21%) | hotspot (GDC flag); catalogued as CS150685, CS941545, COSV52664494, COSV52666095, COSV52685228; called by muse, mutect2, varscan2
- ABCG1 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.089); catalogued as CM138400; called by muse, mutect2, varscan2
- ADGRL3 | c.4163G>T p.R1388L (on ENST00000506720 / NM_001322402.2; = p.R1277L on NM_015236.6) | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.061); catalogued as rs867851537, COSV72229712; called by muse, mutect2
- ASB17 | c.171T>A p.Y57* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as COSV52410657; called by muse, mutect2, varscan2
- CAD | c.3884G>T p.R1295L | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV104391558; called by muse, mutect2, varscan2
- CEP350 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62485674, COSV62485773; called by muse, mutect2
- CNTNAP2 | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV100672003; called by muse, mutect2, varscan2
- CSMD3 | c.8461G>C p.E2821Q (on ENST00000297405 / NM_001363185.1; = p.E2652Q on NM_052900.3) | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.59); catalogued as COSV52164942, COSV99826902; called by muse, mutect2, varscan2
- CYP3A43 | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1302184319; called by muse, mutect2, varscan2
- DCAF12L1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV64422079; called by muse, mutect2, varscan2
- DLC1 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 20/160 reads (13%) | catalogued as rs752937229, COSV52321405; called by muse, mutect2, varscan2
- DMD | c.6184G>T p.A2062S | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as COSV100820174; called by muse, mutect2, varscan2
- DMXL1 | c.8648C>A p.T2883N | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60705839; called by muse, mutect2
- DNAH3 | c.9535C>T p.P3179S | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1194099478; called by muse, mutect2, varscan2
- DNAH8 | c.7423C>A p.P2475T | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs760373475; called by muse, mutect2, varscan2
- ERBB4 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.067); catalogued as COSV99616244; called by muse, mutect2
- ESCO2 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs200548692; called by muse, mutect2, varscan2
- FOSB | c.447G>A p.T149= | Splice Region (SNP) | VAF 12/256 reads (5%) | catalogued as rs1482707393; called by muse, mutect2
- GAREM1 | c.1475C>G p.S492C | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.533); catalogued as COSV52514265; called by muse, mutect2
- GDF2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.614); catalogued as rs782493786; called by muse, mutect2
- GRIN3A | c.1415C>A p.P472H | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100701639; called by muse, mutect2, varscan2
- H1-4 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV56803254, COSV56803481; called by muse, mutect2, varscan2
- H1-7 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1398389521, COSV58601839; called by muse, mutect2
- HEPH | c.2863G>C p.D955H (on ENST00000343002; = p.D688H on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV57959762; called by muse, mutect2, varscan2
- IGHV4-59 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 32/732 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.35); catalogued as rs782357062; called by muse, mutect2
- IMPG1 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.375); catalogued as COSV64054143; called by muse, mutect2, varscan2
- ITGA8 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV65225945; called by muse, mutect2
- ITPRID1 | c.2987C>G p.S996* | Nonsense Mutation (SNP) | VAF 87/365 reads (24%) | catalogued as rs1472423076; called by muse, mutect2, varscan2
- LIMK1 | c.1505A>G p.D502G | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV100282938; called by muse, mutect2, varscan2
- LRIG3 | c.1172+2T>A p.X391_splice | Splice Site (SNP) | VAF 14/178 reads (8%) | catalogued as rs768716699; called by muse, mutect2
- MFSD1 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181700018; called by muse, mutect2, varscan2
- MRC1 | c.4304G>T p.S1435I | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1274860886; called by muse, mutect2
- MYH1 | c.1480C>A p.H494N | Missense Mutation (SNP) | VAF 49/371 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV56845705; called by muse, mutect2, varscan2
- MYH2 | c.4537+1G>T p.X1513_splice | Splice Site (SNP) | VAF 51/389 reads (13%) | catalogued as rs567336764, COSV55435374; called by muse, mutect2, varscan2
- NLRP12 | c.1405C>T p.L469F | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs1421675162; called by muse, mutect2
- NYNRIN | c.3277G>T p.A1093S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs777933278, COSV66841162; called by muse, mutect2, varscan2
- OR2AJ1 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV59089992; called by muse, mutect2, varscan2
- OR2T34 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 15/419 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV60902311; called by muse, mutect2
- PCLO | c.2851C>G p.Q951E | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.945); catalogued as COSV61639342; called by muse, mutect2
- PLXNA1 | c.3806G>A p.R1269H | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs767883494, COSV52524257; called by muse, mutect2
- PRR12 | c.661C>T p.P221S (on ENST00000615927; = p.P1042S on NM_020719.3) | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.879); catalogued as rs1568423499; called by muse, mutect2, varscan2
- PSMD5 | c.713A>T p.H238L | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV52960507; called by muse, varscan2
- PTPRN2 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.053); catalogued as rs138418040; called by muse, mutect2, varscan2
- RASA3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61866022; called by muse, mutect2
- RCC2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.202); catalogued as rs1408678821, COSV64905928; called by muse, mutect2
- RIOK3 | c.93A>G p.I31M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1274869735; called by muse, mutect2, varscan2
- RNF10 | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565958050; called by muse, mutect2
- RTL1 | c.2902G>T p.G968W | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101128298; called by muse, mutect2, varscan2
- SGCZ | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.215); catalogued as COSV66023617; called by muse, mutect2, varscan2
- SLCO1C1 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs771888928, COSV99858851, COSV99858927; called by muse, mutect2, varscan2
- SORCS1 | c.1930C>G p.L644V | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs200162724, COSV53851500; called by muse, mutect2, varscan2
- TECTA | c.5909C>T p.A1970V | Missense Mutation (SNP) | VAF 250/613 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV99878808; called by muse, mutect2, varscan2
- TMEM132D | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.698); catalogued as COSV101399773; called by muse, mutect2
- TNKS | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.409); catalogued as COSV100126355; called by muse, mutect2, varscan2
- TRGV5 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1255930410; called by muse, mutect2, varscan2
- TSEN34 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs374974634, COSV99824877; called by muse, mutect2
- TTN | c.29594C>T p.P9865L (on ENST00000591111; = p.P8938L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/128 reads (17%) | PolyPhen probably damaging (0.994); catalogued as COSV59892151; called by muse, mutect2, varscan2
- USH2A | c.7873G>T p.E2625* | Nonsense Mutation (SNP) | VAF 74/368 reads (20%) | catalogued as rs1259115799, CM149923; called by muse, mutect2, varscan2
- VPS13B | c.1933C>G p.L645V | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV62020437; called by muse, mutect2
- VPS13B | c.4172G>A p.C1391Y | Missense Mutation (SNP) | VAF 45/372 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as rs1192215872; called by muse, mutect2, varscan2
- WDR49 | c.210C>G p.F70L (on ENST00000308378 / NM_001366158.1; = p.F411L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57702022; called by muse, mutect2, varscan2
- ZNF107 | c.1621A>G p.I541V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs988203029; called by muse, varscan2
- ZNF219 | c.994C>A p.R332S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.323); catalogued as COSV53881800; called by muse, mutect2, varscan2
- ZNF729 | c.1553G>A p.C518Y | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748647430; called by muse, mutect2, varscan2
- AASDHPPT | c.758A>G p.H253R | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC100868.1 | c.679C>G p.P227A | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.075); called by muse, mutect2
- ACAT2 | c.459T>A p.D153E | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ACAT2 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- AFF3 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- AGTR2 | c.119C>G p.S40* | Nonsense Mutation (SNP) | VAF 32/161 reads (20%) | called by muse, mutect2, varscan2
- AHR | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.23); called by muse, mutect2
- ALDH4A1 | c.1066G>C p.V356L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1372A>G p.I458V | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.17); called by muse, mutect2
- APOB | c.4827G>C p.L1609F | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ARHGAP15 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ASB18 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 60/396 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ASPM | c.2946G>A p.M982I | Missense Mutation (SNP) | VAF 21/501 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ATCAY | c.380C>G p.A127G | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ATP2B1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- BRSK1 | c.1717+1G>A p.X573_splice | Splice Site (SNP) | VAF 17/212 reads (8%) | called by muse, mutect2
- C12orf65 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 33/476 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.05); called by muse, mutect2
- C7orf31 | c.1551A>C p.E517D | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1B | c.4675-2A>G p.X1559_splice | Splice Site (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2, varscan2
- CACNA1G | c.1887C>G p.Y629* | Nonsense Mutation (SNP) | VAF 51/436 reads (12%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.4898G>C p.G1633A | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CEACAM18 | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.205); called by muse, varscan2
- CFAP54 | c.6494C>T p.S2165L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- CHGB | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 49/351 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CNTN3 | c.140C>G p.T47S | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.141); called by muse, varscan2
- COL19A1 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL27A1 | c.900_906del p.Q301Lfs*155 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | called by mutect2, pindel, varscan2
- COL4A5 | c.4169C>A p.P1390Q | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CRB1 | c.2608A>G p.N870D | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- CREG1 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.142); called by muse, mutect2
- CTAGE1 | c.1337del p.L446* | Frame Shift Del (DEL) | VAF 22/196 reads (11%) | called by mutect2, varscan2
- DACH1 | c.1310C>A p.P437H (on ENST00000619232 / NM_001366712.1; = p.P385H on NM_080759.6) | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- DACH1 | c.1309C>A p.P437T (on ENST00000619232 / NM_001366712.1; = p.P385T on NM_080759.6) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- DCAF1 | c.3960C>A p.D1320E | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.084); called by muse, mutect2
- DCAF4L2 | c.4del p.E2Rfs*33 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- DCAF8L2 | c.23C>A p.T8K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- DCDC1 | c.3375C>A p.D1125E (on ENST00000597505 / NM_001367979.1; = p.D232E on NM_020869.3) | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCHS1 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 61/340 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DDX56 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- DGKB | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP10 | c.1104C>G p.F368L | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYNC1H1 | c.11263G>A p.E3755K | Missense Mutation (SNP) | VAF 28/506 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.258); called by muse, mutect2
- DZIP3 | c.3394T>A p.W1132R | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- EEF2 | c.1924del p.D642Tfs*93 | Frame Shift Del (DEL) | VAF 33/168 reads (20%) | called by mutect2, pindel, varscan2
- EEFSEC | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.528); called by muse, mutect2
- ENOSF1 | c.296G>T p.G99V (on ENST00000340116 / NM_001354066.2; = p.G51V on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EPHB6 | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- FAM217A | c.23G>T p.C8F | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- FAM71B | c.788C>A p.A263E | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT4 | c.14146A>G p.R4716G | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- FKBP15 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.336); called by muse, mutect2
- FLRT1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- FRY | c.1117C>G p.Q373E | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2
- GOLGA6A | c.915A>T p.K305N | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GPR20 | c.112T>C p.F38L | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRHL2 | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 88/484 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HDAC9 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIPK2 | c.1104G>T p.R368S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- HK2 | c.2657G>T p.C886F | Missense Mutation (SNP) | VAF 129/540 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HRNR | c.1435A>T p.T479S | Missense Mutation (SNP) | VAF 140/508 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA12B | c.1707G>A p.W569* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- HTR1F | c.629C>G p.T210R | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- IRX5 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 27/150 reads (18%) | called by muse, mutect2, varscan2
- KCNK18 | c.929T>A p.F310Y | Missense Mutation (SNP) | VAF 21/493 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); called by muse, mutect2
- KCNQ3 | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 74/450 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KIF21A | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KRT73 | c.433T>G p.S145A | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- KSR1 | c.2026G>T p.V676L (on ENST00000644974 / NM_001367810.1; = p.V561L on NM_014238.2) | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- L3MBTL4 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- LHX8 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMOD3 | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPL | c.461A>T p.H154L | Missense Mutation (SNP) | VAF 49/324 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- LRP1 | c.5150A>G p.Y1717C | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MCM4 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- MEOX2 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MIOS | c.2251G>A p.V751M | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MME | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- MTTP | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 26/327 reads (8%) | called by muse, mutect2
- MYH2 | c.1118A>T p.E373V | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- MYLK3 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- N4BP1 | c.1430C>G p.S477* | Nonsense Mutation (SNP) | VAF 56/230 reads (24%) | called by muse, mutect2, varscan2
- NCOA6 | c.5710A>T p.S1904C | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- NDST1 | c.1750G>C p.D584H | Missense Mutation (SNP) | VAF 28/353 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- NES | c.2729A>T p.D910V | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- NFIX | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 56/412 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NOBOX | c.1985A>C p.K662T | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- NOTCH3 | c.1087G>T p.D363Y | Missense Mutation (SNP) | VAF 69/438 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NUDT12 | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- OBSCN | c.2149C>A p.L717M | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- OR52B2 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6N1 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- PCDHGA4 | c.2005C>G p.L669V | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PCNX1 | c.4804A>G p.I1602V | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE3A | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 32/506 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PGM2L1 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, varscan2
- PHF21B | c.1031G>T p.C344F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHLPP1 | c.4438G>A p.E1480K | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PKHD1 | c.3096T>C p.I1032= | Splice Region (SNP) | VAF 36/203 reads (18%) | called by muse, mutect2, varscan2
- PNPLA7 | c.1320T>A p.D440E | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPP1R12C | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2
- PREX1 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRR15 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR32 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- PTPN3 | c.1022G>T p.C341F | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.05); called by muse, mutect2
- PTPRM | c.2926C>G p.Q976E | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RAB3IL1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAI14 | c.2920A>T p.K974* | Nonsense Mutation (SNP) | VAF 22/258 reads (9%) | called by muse, mutect2
- RAPGEF3 | c.1061T>A p.M354K (on ENST00000389212; = p.M312K on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- RASSF2 | c.110A>G p.Q37R | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- RELN | c.4277T>A p.V1426E | Missense Mutation (SNP) | VAF 44/368 reads (12%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SCN10A | c.3566C>A p.T1189N | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SEL1L2 | c.1289C>A p.A430D | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGSH | c.935A>G p.Y312C | Missense Mutation (SNP) | VAF 45/360 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SLC43A2 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNX30 | c.1292A>C p.Q431P | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPOCK2 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SSC5D | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TAS1R2 | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2
- TIMM44 | c.808A>G p.N270D | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM161B | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- TP53RK | c.206A>C p.H69P | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TRAM1L1 | c.937T>C p.W313R | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM13 | c.162T>A p.C54* | Nonsense Mutation (SNP) | VAF 27/170 reads (16%) | called by muse, mutect2, varscan2
- TRIM52 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 61/428 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTLL13P | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 13/313 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2
- TTN | c.28000G>A p.D9334N (on ENST00000591111; = p.D8407N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/213 reads (16%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNDC16 | c.2284A>T p.R762W | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- UBAP2 | c.2318C>G p.T773S | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- USH2A | c.7433C>A p.S2478Y | Missense Mutation (SNP) | VAF 101/428 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VEPH1 | c.433T>C p.C145R | Missense Mutation (SNP) | VAF 45/346 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS41 | c.650T>G p.M217R | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- WDR5 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- XRRA1 | c.1070A>G p.K357R | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2
- ZDHHC8 | c.557+1G>T p.X186_splice | Splice Site (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- ZMYND11 | c.565A>G p.R189G | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.236); called by muse, mutect2
- ZNF440 | c.767A>T p.Y256F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- ZNF713 | c.65A>T p.Q22L (on ENST00000633730 / NM_001366796.2; = p.Q35L on NM_182633.3) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- A2M | c.3642C>T p.L1214= | Silent (SNP) | VAF 34/616 reads (6%) | catalogued as rs775335536, COSV100588907; called by muse, mutect2
- ACTN4 | c.504G>T p.G168= | Silent (SNP) | VAF 42/368 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.1437G>A p.Q479= | Silent (SNP) | VAF 24/337 reads (7%) | catalogued as rs1164727465; called by muse, mutect2
- ADAMTS12 | c.990C>A p.P330= | Silent (SNP) | VAF 35/208 reads (17%) | called by muse, varscan2
- AHR | c.1896G>T p.V632= | Silent (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- APBA3 | c.1335C>T p.T445= | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as rs559315705; called by muse, mutect2
- C16orf71 | c.582G>T p.V194= | Silent (SNP) | VAF 9/194 reads (5%) | called by muse, mutect2
- CACNA1C | c.1620C>T p.T540= | Silent (SNP) | VAF 16/216 reads (7%) | catalogued as rs893883530; ClinVar: likely benign; called by muse, mutect2
- CAPRIN2 | c.978G>A p.K326= | Silent (SNP) | VAF 66/206 reads (32%) | called by muse, varscan2
- CCDC190 | c.63C>T p.A21= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as rs778694428; called by muse, mutect2
- CHRM2 | c.348C>T p.I116= | Silent (SNP) | VAF 44/504 reads (9%) | catalogued as COSV57784326; called by muse, mutect2
- CSMD3 | c.4803A>T p.S1601= (on ENST00000297405 / NM_001363185.1; = p.S1497= on NM_052900.3) | Silent (SNP) | VAF 28/358 reads (8%) | called by muse, mutect2
- DAZL | c.384T>A p.P128= | Silent (SNP) | VAF 21/164 reads (13%) | called by muse, mutect2, varscan2
- DCUN1D1 | c.444G>A p.L148= | Silent (SNP) | VAF 185/313 reads (59%) | called by muse, mutect2, varscan2
- DDX53 | c.321G>T p.A107= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV60069376; called by muse, mutect2, varscan2
- DUOXA2 | c.420G>A p.A140= | Silent (SNP) | VAF 22/337 reads (7%) | catalogued as COSV50993638, COSV99973607; called by muse, mutect2
- ENOSF1 | c.297G>T p.G99= (on ENST00000340116 / NM_001354066.2; = p.G51= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/226 reads (11%) | called by muse, mutect2, varscan2
- FMN2 | c.2289G>C p.L763= | Silent (SNP) | VAF 66/276 reads (24%) | called by muse, mutect2, varscan2
- GALNTL6 | c.135G>A p.Q45= | Silent (SNP) | VAF 39/315 reads (12%) | called by muse, mutect2, varscan2
- GLI3 | c.2475G>T p.T825= | Silent (SNP) | VAF 83/597 reads (14%) | catalogued as COSV67894138; called by muse, mutect2, varscan2
- GPM6A | c.327C>T p.A109= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as COSV54538195; called by muse, mutect2, varscan2
- GPRC6A | c.2226G>A p.L742= | Silent (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- GRIP1 | c.528A>G p.K176= | Silent (SNP) | VAF 117/362 reads (32%) | catalogued as rs1287013641; called by muse, mutect2, varscan2
- HEY1 | c.760C>T p.L254= | Silent (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- IGHV3-30 | c.174G>A p.Q58= | Silent (SNP) | VAF 62/675 reads (9%) | catalogued as rs1384061788; called by muse, mutect2
- IGHV3-73 | c.168C>T p.V56= | Silent (SNP) | VAF 45/310 reads (15%) | called by muse, mutect2, varscan2
- IL22RA2 | c.273A>G p.P91= | Silent (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- IQCJ-SCHIP1 | c.36T>A p.P12= | Silent (SNP) | VAF 71/252 reads (28%) | called by muse, mutect2, varscan2
- IRS2 | c.888G>A p.E296= | Silent (SNP) | VAF 44/274 reads (16%) | catalogued as rs763825043; called by muse, mutect2, varscan2
- JPH2 | c.849C>A p.I283= | Silent (SNP) | VAF 40/379 reads (11%) | catalogued as rs1286994114, COSV65904878; called by muse, varscan2
- KCNQ2 | c.1155C>T p.I385= (on ENST00000359125 / NM_172107.4; = p.I375= on NM_004518.6) | Silent (SNP) | VAF 21/169 reads (12%) | catalogued as rs1182444283, COSV60549351; called by muse, mutect2, varscan2
- KIAA0319L | c.2331G>T p.R777= | Silent (SNP) | VAF 13/168 reads (8%) | called by muse, mutect2
- KMT2A | c.2469G>A p.P823= | Silent (SNP) | VAF 12/393 reads (3%) | catalogued as COSV100629123; called by muse, mutect2
- LILRB1 | c.624C>A p.P208= (on ENST00000427581; = p.P172= on NM_006669.6) | Silent (SNP) | VAF 48/459 reads (10%) | called by muse, mutect2, varscan2
- MAP1S | c.1053C>T p.G351= | Silent (SNP) | VAF 32/242 reads (13%) | catalogued as rs1452153222; called by muse, mutect2, varscan2
- MAS1L | c.406C>T p.L136= | Silent (SNP) | VAF 31/167 reads (19%) | called by muse, varscan2
- MBL2 | c.492C>A p.T164= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as rs771050855; called by muse, mutect2, varscan2
- MOS | c.450C>A p.V150= | Silent (SNP) | VAF 34/250 reads (14%) | called by muse, mutect2, varscan2
- MTNR1A | c.435C>G p.L145= | Silent (SNP) | VAF 26/386 reads (7%) | catalogued as COSV56154891; called by muse, mutect2
- MUC16 | c.39132G>A p.Q13044= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV67473744; called by muse, mutect2, varscan2
- MUC19 | c.321T>C p.F107= | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- OR10K2 | c.636G>A p.L212= | Silent (SNP) | VAF 66/290 reads (23%) | catalogued as COSV100149579; called by muse, mutect2, varscan2
- OR1S1 | c.384G>A p.L128= | Silent (SNP) | VAF 43/242 reads (18%) | catalogued as COSV58707079; called by muse, mutect2, varscan2
- OR52L1 | c.315T>C p.V105= | Silent (SNP) | VAF 36/206 reads (17%) | catalogued as rs765872601; called by muse, mutect2, varscan2
- PCDH10 | c.699G>T p.T233= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as rs1376998823, COSV52100154; called by muse, mutect2
- PCDHA3 | c.1845C>A p.T615= | Silent (SNP) | VAF 34/277 reads (12%) | catalogued as rs373825257, COSV100793463; called by muse, mutect2, varscan2
- PCDHGA11 | c.1344T>C p.D448= | Silent (SNP) | VAF 54/328 reads (16%) | called by muse, mutect2, varscan2
- PPFIA2 | c.2892A>C p.L964= | Silent (SNP) | VAF 39/261 reads (15%) | called by muse, mutect2, varscan2
- RBM3 | c.36G>T p.G12= | Silent (SNP) | VAF 43/191 reads (23%) | catalogued as COSV63202511; called by muse, mutect2, varscan2
- RBP3 | c.717C>G p.A239= | Silent (SNP) | VAF 42/231 reads (18%) | called by muse, mutect2, varscan2
- SASH3 | c.573C>T p.H191= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as rs1432141495, COSV63556752; called by muse, mutect2, varscan2
- SETBP1 | c.2127G>C p.L709= | Silent (SNP) | VAF 16/436 reads (4%) | called by muse, mutect2
- SH3D19 | c.1200C>T p.P400= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.1605G>A p.Q535= | Silent (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- TAAR9 | c.273G>T p.V91= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs878859311; called by muse, mutect2, varscan2
- TAS2R31 | c.543G>T p.T181= | Silent (SNP) | VAF 58/166 reads (35%) | called by muse, mutect2, varscan2
- TEX2 | c.1395C>T p.A465= | Silent (SNP) | VAF 32/236 reads (14%) | catalogued as rs1162532047, COSV51981362; called by muse, mutect2, varscan2
- TMEM229A | c.1119G>A p.R373= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs1210670020; called by muse, varscan2
- TRIM64C | c.1278T>G p.G426= | Silent (SNP) | VAF 49/263 reads (19%) | called by muse, mutect2, varscan2
- TRPC1 | c.534C>G p.L178= (on ENST00000476941 / NM_001251845.2; = p.L144= on NM_003304.4) | Silent (SNP) | VAF 50/299 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.6024C>A p.G2008= (on ENST00000591111; = p.G1962= on NM_003319.4) | Silent (SNP) | VAF 8/139 reads (6%) | called by muse, mutect2
- WDR33 | c.2913A>G p.S971= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- ZNF569 | c.1944T>G p.S648= | Silent (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- ZNF75D | c.756G>A p.L252= | Silent (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- ZNF865 | c.957G>T p.T319= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- ZNF90 | c.636G>A p.R212= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- AC007218.1 | n.123G>A | RNA (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- AC026410.1 | n.829G>C | RNA (SNP) | VAF 24/331 reads (7%) | called by muse, mutect2
- ADD3-AS1 | n.6100C>G | RNA (SNP) | VAF 34/249 reads (14%) | called by muse, mutect2, varscan2
- AGPAT5 | c.219+109C>G | Intron (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.2088G>A | RNA (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- ARPP21 | c.261+220G>T | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2
- BIRC3 | c.953+1198G>A | Intron (SNP) | VAF 18/372 reads (5%) | catalogued as rs773246934; called by muse, mutect2
- CACNA1D | c.5040+75C>G | Intron (SNP) | VAF 27/354 reads (8%) | called by muse, mutect2
- CELSR1 | c.7760-227G>T | Intron (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- CEP126 | c.507-1654A>C | Intron (SNP) | VAF 91/378 reads (24%) | called by muse, mutect2, varscan2
- COL1A2 | c.1864-44C>A | Intron (SNP) | VAF 19/236 reads (8%) | called by muse, mutect2
- CPSF4 | c.155-268G>A | Intron (SNP) | VAF 8/49 reads (16%) | catalogued as rs1262883397; called by muse, mutect2, varscan2
- ELMO2 | c.119+20G>A | Intron (SNP) | VAF 12/221 reads (5%) | catalogued as rs1361878560; called by muse, mutect2
- FAM182B | n.730G>A | RNA (SNP) | VAF 27/285 reads (9%) | catalogued as rs1241704130; called by muse, mutect2
- GOLGA3 | c.3267+32G>T | Intron (SNP) | VAF 26/228 reads (11%) | catalogued as rs370130724, COSV52630412; called by muse, mutect2, varscan2
- KLHL14 | c.-44+516_-44+518del | Intron (DEL) | VAF 4/38 reads (11%) | catalogued as rs780568428; called by mutect2, pindel
- LRRC37A6P | n.1454C>G | RNA (SNP) | VAF 35/218 reads (16%) | called by muse, mutect2, varscan2
- MIR6859-4 | chr16:17405 A>T | 5'Flank (SNP) | VAF 26/193 reads (13%) | called by muse, varscan2
- NDUFA8 | c.-44G>T | 5'UTR (SNP) | VAF 14/180 reads (8%) | catalogued as COSV101055796; called by muse, mutect2
- NTRK2 | c.1397-56637G>T | Intron (SNP) | VAF 33/198 reads (17%) | called by muse, mutect2, varscan2
- PDGFRA | c.*12G>C | 3'UTR (SNP) | VAF 12/110 reads (11%) | catalogued as COSV57271748; called by muse, mutect2
- PKIG | chr20:44623952 G>T | 3'Flank (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- POTEM | c.1409+4022G>T | Intron (SNP) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- PRKCB | c.174-40C>G | Intron (SNP) | VAF 70/352 reads (20%) | called by muse, mutect2, varscan2
- QARS1 | c.266-73C>A | Intron (SNP) | VAF 37/219 reads (17%) | called by muse, mutect2, varscan2
- RMDN3 | c.808-56C>T | Intron (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158752 C>A | 5'Flank (SNP) | VAF 29/185 reads (16%) | catalogued as rs554739358; called by muse, mutect2, varscan2
- SPATA21 | c.145-800C>A | Intron (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- SSPOP | n.11391C>T | RNA (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2
- SYNE1 | c.2569-649G>T | Intron (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- SYNE1 | c.2569-650G>T | Intron (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- TBX1 | c.*14G>A | 3'UTR (SNP) | VAF 37/329 reads (11%) | called by muse, mutect2, varscan2
- TDH | chr8:11347390 G>C | 5'Flank (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.269-131G>T | Intron (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- TRAF3 | c.*10G>T | 3'UTR (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- TUSC3 | c.1028+82G>C | Intron (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- ZNF419 | c.199+9C>G | Intron (SNP) | VAF 26/418 reads (6%) | catalogued as rs1393953350; called by muse, mutect2
